Somatic mutation profile of tumor specimen TCGA-AR-A24U-01A (aliquot TCGA-AR-A24U-01A-11D-A167-09) from TCGA case TCGA-AR-A24U, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 48.0 years (17,523 days).
Specimen TCGA-AR-A24U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e17f098e-9cb6-4706-8156-09a43b8cd953.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A24U-10A (Blood Derived Normal), aliquot TCGA-AR-A24U-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d89e9f6c-6721-4a11-bad9-6777a6eeeb21

The open-access MAF lists 41 somatic variants for this specimen: 33 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 27, Silent 8, Nonsense Mutation 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as rs1567556930, COSV52694020, COSV53536519; ClinVar: pathogenic; called by muse, mutect2
- ABI3BP | c.1274C>T p.T425I | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs896497214, COSV52549787; called by mutect2, varscan2
- ASB11 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100729094; called by muse, mutect2
- DAXX | c.1142T>G p.M381R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.359); catalogued as COSV56472412; called by muse, mutect2, varscan2
- ECSIT | c.776C>G p.P259R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as COSV99369155; called by muse, mutect2, varscan2
- ERO1B | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV99934597; called by muse, mutect2, varscan2
- IKZF1 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.136); catalogued as COSV58785613, COSV58788959; called by muse, mutect2
- IL18RAP | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as rs969563592, COSV99962210; called by muse, mutect2
- IMPG2 | c.2134G>A p.V712I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140592059; called by muse, mutect2, varscan2
- IPO9 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV100843502; called by muse, mutect2
- JMJD1C | c.6956C>A p.A2319D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550723; called by muse, mutect2
- KLHL4 | c.72T>A p.H24Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV64147348; called by muse, mutect2, varscan2
- MED1 | c.3368C>G p.S1123* | Nonsense Mutation (SNP) | VAF 17/201 reads (8%) | catalogued as COSV100327996; called by muse, mutect2
- MIA2 | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | catalogued as COSV99696838; called by muse, mutect2
- NCF4 | c.359C>G p.P120R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50627679, COSV50630011; called by muse, mutect2, varscan2
- NCOA5 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV51647080; called by muse, mutect2, varscan2
- NLRP2 | c.3136G>T p.E1046* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as COSV54761276, COSV99672468; called by muse, mutect2
- OR4X2 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.221); catalogued as COSV100183287; called by muse, mutect2
- PDCD10 | c.21G>C p.E7D | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated, low confidence (0.61); PolyPhen possibly damaging (0.836); catalogued as COSV67102336, COSV67103130; called by muse, mutect2, varscan2
- PHF12 | c.2423T>A p.V808E | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99255994; called by muse, mutect2
- PIK3C2A | c.4297C>T p.H1433Y | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV99791012; called by muse, mutect2
- PRKAR1A | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as COSV56835672; called by muse, mutect2, varscan2
- SAMD12 | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100126470; called by muse, varscan2
- TM4SF19 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as COSV56557537; called by muse, varscan2
- TNFRSF11A | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs934154488, COSV54025959; called by muse, mutect2, varscan2
- TNPO3 | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs1563104400, COSV55286294; called by muse, mutect2, varscan2
- TTN | c.67957G>A p.E22653K (on ENST00000591111; = p.E15229K on NM_003319.4) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | PolyPhen probably damaging (0.994); catalogued as COSV100621522; called by muse, mutect2
- TTN | c.67150G>C p.E22384Q (on ENST00000591111; = p.E14960Q on NM_003319.4) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | PolyPhen probably damaging (0.964); catalogued as COSV60311026; called by muse, mutect2, varscan2
- UBR5 | c.4639C>T p.R1547C | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as rs758390848, COSV99641617; called by muse, mutect2
- UGP2 | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55444846; called by muse, mutect2, varscan2
- WDR7 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1169391500; called by muse, mutect2
- CIP2A | c.851T>C p.V284A | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- RUNX1 | c.804_810del p.V269Qfs*13 (on ENST00000344691 / NM_001001890.3; = p.V296Qfs*13 on NM_001754.5) | Frame Shift Del (DEL) | VAF 30/80 reads (38%) | called by mutect2, pindel, varscan2
- ABCB11 | c.3909G>A p.L1303= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as COSV55600000; called by muse, mutect2, varscan2
- COL20A1 | c.825C>G p.G275= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV58926431; called by muse, mutect2
- FGGY | c.933C>T p.G311= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs1161182007, COSV58035342; called by muse, mutect2, varscan2
- LIPE | c.1938G>A p.L646= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV54925203, COSV54925920; called by muse, mutect2, varscan2
- MAGEA12 | c.714C>G p.V238= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV63295402; called by muse, mutect2, varscan2
- OTOGL | c.6744G>A p.G2248= (on ENST00000547103; = p.G2239= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV54013262, COSV54018174; called by muse, mutect2, varscan2
- SAMD12 | c.226C>T p.L76= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV100126473, COSV59052469; called by muse, varscan2
- TTN | c.68367G>A p.L22789= (on ENST00000591111; = p.L15365= on NM_003319.4) | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100617433; called by muse, mutect2
